Gene-level copy-number profile of tumor specimen TCGA-D7-8575-01A from TCGA case TCGA-D7-8575, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 75.9 years (27,712 days).
Specimen TCGA-D7-8575-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.ead9cd81-8402-4586-94d8-3f97081298ec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-8575-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4484b4d0-ba03-44c1-8020-c60866a20446

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 85; copy number 1: 15,890; copy number 2: 38,718; copy number 3: 2,434; copy number 4: 2,324; copy number 5: 20; copy number 7: 99; copy number 9: 34; copy number 11: 99; copy number 14: 19; copy number 17: 48; copy number 28: 25; copy number 34: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-8575-01A-11D-2338-01): tumor purity 0.66, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:176,495,255–176,819,180, 1 gene (within-gene range 0–2): LINC01117.
- chr2:176,600,980–177,223,958, 18 genes: MIR1246, AC017048.3, LINC01116, RNU6ATAC14P, AC092162.2, FUCA1P1, AC092162.1, AC092162.3, AC073636.1, RNU6-187P, AC074286.1, AC079305.2, RNA5SP112, STUB1P1, Y_RNA, KRT8P40, HNRNPA3, MIR4444-1.
- chr2:177,229,191–177,265,515, 3 genes: DNAJC19P5, MIR3128, AC079305.1.
- chr2:186,590,056–186,680,901, 1 gene (within-gene range 0–3): ITGAV.
- chr9:21,058,771–22,029,594, 45 genes (within-gene range 0–1): IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3.
- chr15:37,921,939–39,180,499, 14 genes (within-gene range 0–1): TMCO5A, LINC02345, LINC01852, AC087473.1, SPRED1, FAM98B, AC109631.1, RASGRP1, AC116158.3, AC116158.1, AC116158.2, LINC02694, AC022929.1, AC022929.2.
- chr15:39,019,193–39,026,521, 1 gene: AC087878.1.
- chr20:15,021,553–15,022,958, 2 genes: RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 366 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:97,851,688–97,972,985, 1 gene, copy number 5 (within-gene range 1–5): AC079781.5.
- chr7:97,898,347–99,534,700, 47 genes, copy number 5–9: RPS3AP29, AC079781.1, AC079781.2, AC079781.4, AC079781.3, OR7E7P, MIR5692A1, MIR5692C2, OR7E38P, AC004967.2, AC004967.1, OCM2, RN7SL478P, LMTK2, BHLHA15, TECPR1, BRI3, BAIAP2L1, AC093799.1, RPS3AP26, PPIAP82, AC074121.1, NPTX2, RNU6-393P, TMEM130, TRRAP, MIR3609, AC004893.2, RNF14P3, SMURF1, AC004893.1, KPNA7, MYH16, AC004834.1, AC004922.1, ARPC1A, ARPC1B, PDAP1, BUD31, PTCD1, ATP5MF-PTCD1, CPSF4, AC073063.1, ATP5MF, ZNF789, ZNF394, ZKSCAN5.
- chr7:99,952,033–100,968,347, 78 genes, copy number 7 (broad region; genes not listed).
- chr8:10,482,878–10,547,585, 1 gene, copy number 11 (within-gene range 4–11): PRSS51.
- chr8:10,525,532–12,665,588, 98 genes, copy number 11 (broad region; genes not listed).
- chr10:59,176,643–62,096,944, 27 genes, copy number 5–7: PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845, TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B.
- chr12:18,493,051–18,493,723, 1 gene, copy number 17: ZKSCAN7P1.
- chr12:19,129,752–26,335,856, 113 genes, copy number 14–34 (within-gene range 3–34) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,503. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
